TCGA case TCGA-A2-A25E — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ba89cb4f-cd63-47b1-9550-76fdaff89f2e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 34 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 34.5 years (12,601 days); Year of diagnosis: 2004; Method of diagnosis: Excisional Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 10; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 67 days; Days to treatment end: 136 days; Number of cycles: 4; Treatment dose: 3,600 mg; Prescribed dose: 900; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 67 days; Days to treatment end: 136 days; Number of cycles: 4; Treatment dose: 360 mg; Prescribed dose: 90; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 158 days; Days to treatment end: 242 days; Number of cycles: 12; Treatment dose: 1,440 mg; Prescribed dose: 120; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 250 days; Days to treatment end: 601 days (1.6 years); Number of cycles: 47; Treatment dose: 5,142 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 292 days; Days to treatment end: 333 days; Treatment dose: 10,640 cGy; Course number: 1; Number of fractions: 84; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 334 days; Days to treatment end: 2,155 days (5.9 years); Prescribed dose: 10; Prescribed dose units: mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Goserelin; Treatment intent type: Prevention; Days to treatment start: 2,380 days (6.5 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 3.6; Prescribed dose units: mg; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: 3,055 days (8.4 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Thorax, NOS. Age at diagnosis: 42.7 years (15,590 days); Days to diagnosis: 2,989 days (8.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 3,024 days (8.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 2,511 days (6.9 years); Disease response: Tumor Free.
- Days to follow up: 2,796 days (7.7 years); Disease response: Tumor Free.
- Day 2,989 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 2,989 days (8.2 years).
- Days to follow up: 3,204 days (8.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 2.1; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+.
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ERBB2 amplification (FISH): Equivocal.
- ESR1 (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 3+; Test value range: 90-99%.
- ESR1 (IHC): Positive; Test value range: 80-89%.
- PGR (IHC): Positive; Staining intensity scale: 3 Point Scale; Staining intensity value: 2+; Test value range: <10%.
- PGR (IHC): Positive; Test value range: 60-69%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A25E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 200 mg.
  Slide TCGA-A2-A25E-01A-01-TSA: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 26; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A25E-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A25E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Her2 cent17 ratio: 2.1; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Her2 IHC score: 2+; Pr positivity scale other: Strong, using scale of Weak, Moderate and Strong; Er positivity scale other: Moderate using scale of Weak, Moderate, Strong; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Outer Quadrant.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free.
- Drug treatment 1: Regimen number: 4; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 5; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 4: Regimen number: 3; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 5: Regimen number: 6; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Preventative.
- Drug treatment 5, Route of administrations: Route of administration: SC.
- Drug treatment 6: Regimen number: 2.
- Drug treatment 6, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,204 days; disease-specific survival: no event (censored), 3,204 days; disease-free interval: event (new tumor event after initially disease-free), 2,989 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,989 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A25E-01A-11D-A166-01): tumor purity 0.66, ploidy 2.11, whole-genome doublings 0.
